Somatic mutation profile of tumor specimen ALCH-B21A-TTP1-A (aliquot ALCH-B21A-TTP1-A-2-0-D-A76I-36) from ALCHEMIST case ALCH-B21A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.8 years (24,389 days).
Specimen ALCH-B21A-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fe33abd-8e4d-49ec-8f0c-68304ec44b7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B21A-NB1-A (Blood Derived Normal), aliquot ALCH-B21A-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95e0c72c-f7dd-4f80-8b11-feb05e336034

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCDC1 | c.4249T>C p.Y1417H (on ENST00000597505 / NM_001367979.1; = p.Y524H on NM_020869.3) | Missense Mutation (SNP) | VAF 20/419 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- LSMEM1 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF185 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2
- ABCA1 | c.2988C>T p.F996= | Silent (SNP) | VAF 38/646 reads (6%) | catalogued as rs886063310; called by muse, mutect2
